Somatic mutation profile of tumor specimen TCGA-DB-A64Q-01A (aliquot TCGA-DB-A64Q-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64Q, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.9 years (11,637 days).
Specimen TCGA-DB-A64Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f318c813-e6d3-4e8a-9881-930af4d2aba2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64Q-10A (Blood Derived Normal), aliquot TCGA-DB-A64Q-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd10dad5-1b64-4d8d-b173-12fcd1b4db33

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 58/84 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- EML1 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV51750940; called by muse, mutect2, varscan2
- ENPP1 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as rs763005831, COSV62935311; called by muse, mutect2, varscan2
- FUBP1 | c.940+2T>G p.X314_splice | Splice Site (SNP) | VAF 18/31 reads (58%) | catalogued as COSV53936835; called by muse, mutect2, varscan2
- HSPA4L | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as COSV56547792; called by muse, mutect2, varscan2
- IGLC3 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 47/120 reads (39%) | PolyPhen benign (0.059); catalogued as rs8307; called by muse, mutect2, varscan2
- ITIH6 | c.3493T>C p.S1165P | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54493229; called by muse, mutect2, varscan2
- KIDINS220 | c.4100A>G p.D1367G | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as COSV56757949; called by muse, mutect2, varscan2
- LLGL2 | c.2968A>G p.I990V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV51392383; called by muse, mutect2, varscan2
- MLLT3 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV63500758; called by muse, mutect2, varscan2
- PALM | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs202021174, COSV52770366; called by muse, mutect2, varscan2
- SYNJ1 | c.1441G>A p.G481R | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59154727; called by muse, mutect2
- TREML2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72439213; called by muse, mutect2, varscan2
- VRTN | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs773931361, COSV56443122; called by muse, mutect2, varscan2
- RTL5 | c.284del p.E95Gfs*10 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- DCAF6 | c.447T>C p.T149= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV56583673; called by muse, mutect2, varscan2
- GLT6D1 | c.657G>A p.P219= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs201383603, COSV65627181; called by muse, mutect2, varscan2
- POLQ | c.6945A>T p.R2315= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV51759195; called by muse, mutect2, varscan2
- TEAD1 | c.462G>A p.P154= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as rs752862372, COSV57567740; called by muse, mutect2, varscan2
- XRN1 | c.1383G>A p.Q461= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV53816763; called by muse, mutect2, varscan2
- CD300LD | c.40+112T>A | Intron (SNP) | VAF 49/183 reads (27%) | catalogued as COSV60084465; called by muse, mutect2, varscan2
